HCMI case HCM-BROD-0052-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3d06ca77-a9a1-4e52-9b3d-a6f4f98167d6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1988; Vital status: Dead; Days to death: 150 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/3; ICD-10 code: C49.9; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Classification of tumor: primary; Age at diagnosis: 25.9 years (9,446 days); AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic M: M1; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Sites of involvement: Abdomen.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan + Temozolomide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 89 days; Days to treatment end: 150 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Gemcitabine Hydrochloride; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 150 days; Days to treatment end: 150 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 0 days.
- Days to follow up: 150 days; Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 25.
- Timepoint category: Prior to Diagnosis; Risk factors: Escherichia coli.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0052-C49-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0052-C49-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0052-C49-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0052-C49-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 14.
